Somatic mutation profile of tumor specimen TCGA-DD-A4NP-01A (aliquot TCGA-DD-A4NP-01A-11D-A28X-10) from TCGA case TCGA-DD-A4NP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 32.4 years (11,838 days).
Specimen TCGA-DD-A4NP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d3329f2-f514-437c-a114-9bcd458a43c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NP-10A (Blood Derived Normal), aliquot TCGA-DD-A4NP-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04341fd6-7bc6-460a-9d0e-1c97b425aa9a

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, In Frame Del 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.3223G>A p.V1075I | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs912743717, COSV52368418, COSV52368929; called by muse, varscan2
- APC | c.423-2A>G p.X141_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as CS043351, CS051678, CS106641, COSV57332461; called by mutect2, varscan2
- BET1 | c.21T>C p.G7= | Splice Region (SNP) | VAF 15/42 reads (36%) | catalogued as COSV55992731; called by muse, mutect2, varscan2
- EXOC3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV59266062; called by muse, varscan2
- FAM169A | c.829A>G p.M277V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs748457895, COSV65846220; called by muse, mutect2
- HDAC3 | c.696C>G p.Y232* | Nonsense Mutation (SNP) | VAF 49/165 reads (30%) | catalogued as COSV59495356; called by muse, mutect2, varscan2
- HSPA5 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV61028797; called by muse, mutect2, varscan2
- IL6ST | c.583_588del p.E195_V196del | In Frame Del (DEL) | VAF 38/142 reads (27%) | catalogued as COSV61143304; called by mutect2, pindel, varscan2
- LIF | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1422604609, COSV50776490; called by muse, mutect2
- LRRTM3 | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV63662867; called by muse, mutect2, varscan2
- MYH14 | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369826983, CM1412844; called by muse, mutect2, varscan2
- NRAP | c.3121T>A p.Y1041N (on ENST00000359988 / NM_001322945.2; = p.Y1006N on NM_006175.4) | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.99); catalogued as COSV63489168; called by muse, mutect2, varscan2
- OR4M2 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60306783; called by muse, mutect2, varscan2
- PPP1R12B | c.2134C>A p.L712M | Missense Mutation (SNP) | VAF 136/366 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.275); catalogued as COSV51782762; called by muse, mutect2, varscan2
- RPS6KA1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs952329099, COSV64809696; called by muse, mutect2, varscan2
- SLC19A1 | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV60753529; called by muse, mutect2, varscan2
- WNT1 | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53295493; called by muse, mutect2, varscan2
- ZNF451 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.704); catalogued as COSV62597033; called by muse, mutect2
- ZNF800 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56174426, COSV56174597; called by muse, mutect2, varscan2
- TUBB2A | c.469del p.E157Kfs*8 | Frame Shift Del (DEL) | VAF 36/107 reads (34%) | called by mutect2, varscan2
- NSD3 | c.4191T>A p.S1397= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV57667993; called by muse, mutect2, varscan2
- SART3 | c.1506A>G p.R502= (on ENST00000228284; = p.R484= on NM_014706.4) | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as COSV57206172; called by muse, mutect2, varscan2
- SCN10A | c.1848C>A p.I616= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV71860709, COSV71861766; called by muse, mutect2, varscan2
- TMEM79 | c.129A>C p.G43= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV55293805; called by muse, mutect2, varscan2
